Somatic mutation profile of tumor specimen TCGA-MQ-A4KX-01A (aliquot TCGA-MQ-A4KX-01A-11D-A34C-32) from TCGA case TCGA-MQ-A4KX, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 55.7 years (20,336 days).
Specimen TCGA-MQ-A4KX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3e09991-c222-4d78-9d80-14e68f51ffe8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MQ-A4KX-10B (Blood Derived Normal), aliquot TCGA-MQ-A4KX-10B-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c574bc0d-bca3-479e-a5b0-d766543794eb

The open-access MAF lists 23 somatic variants for this specimen: 14 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 8, Nonsense Mutation 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP3B2 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.121); catalogued as rs1486529587, COSV55607359; called by muse, mutect2, varscan2
- BAP1 | c.271T>G p.C91G | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56231827, COSV56234417; called by muse, mutect2, varscan2
- CCDC63 | c.1447C>A p.P483T | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372078813; called by muse, mutect2, varscan2
- POLR2A | c.168dup p.L57Afs*10 | Frame Shift Ins (INS) | VAF 11/65 reads (17%) | catalogued as rs1567700700; called by mutect2, varscan2
- THRAP3 | c.103C>T p.R35* | Nonsense Mutation (SNP) | VAF 5/89 reads (6%) | catalogued as COSV63566908; called by muse, mutect2
- COL5A2 | c.1598A>T p.D533V | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- GBA3 | c.161G>A p.G54D | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (1); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- HK1 | c.1231G>C p.G411R | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- IQCB1 | c.1740G>C p.K580N | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- MATN4 | c.430A>C p.I144L | Missense Mutation (SNP) | VAF 3/18 reads (17%) | PolyPhen possibly damaging (0.533); called by muse, mutect2
- NEXMIF | c.2401G>C p.A801P | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NUGGC | c.29A>T p.Q10L | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- PGLYRP1 | c.332G>T p.W111L | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UTP25 | c.13G>T p.G5W | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- AGPS | c.405C>T p.T135= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs1332577384; called by muse, mutect2, varscan2
- CDC25C | c.507C>T p.P169= | Silent (SNP) | VAF 20/96 reads (21%) | called by muse, mutect2, varscan2
- MUC16 | c.35103T>G p.V11701= | Silent (SNP) | VAF 4/86 reads (5%) | called by muse, mutect2
- PLBD2 | c.1434G>C p.L478= | Silent (SNP) | VAF 23/160 reads (14%) | catalogued as COSV55108063, COSV55109584; called by muse, mutect2, varscan2
- TBL1X | c.492G>A p.A164= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs1368003808; called by muse, mutect2, varscan2
- TFIP11 | c.951G>T p.L317= | Silent (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
- TRIM71 | c.2043G>A p.T681= | Silent (SNP) | VAF 22/134 reads (16%) | catalogued as rs761536522, COSV67470096; called by muse, mutect2, varscan2
- ZZEF1 | c.4278A>G p.L1426= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs757169579; called by muse, mutect2, varscan2
- METTL16 | n.1113T>C | RNA (SNP) | VAF 6/30 reads (20%) | catalogued as rs1051619919; called by muse, mutect2, varscan2
